HCMI case HCM-BROD-0102-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/88335768-5a27-4b29-b3bc-72e53b87015b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Dead; Days to death: 973 days (2.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,280 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -12 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 512 days (1.4 years); Days to treatment end: 720 days (2.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 526 days (1.4 years); Days to treatment end: 720 days (2.0 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 776 days (2.1 years); Days to treatment end: 895 days (2.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 804 days (2.2 years); Days to treatment end: 837 days (2.3 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 916 days (2.5 years); Days to treatment end: 963 days (2.6 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (3 entries)
- Days to follow up: 13 days; Karnofsky performance status: 80.
- Days to follow up: 973 days (2.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 0, day 778.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52.5 kg; Height: 156.6 cm; BMI: 21.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0102-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0102-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 2.
